Somatic mutation profile of tumor specimen C3L-00279-02 (aliquot CPT0082740010) from CPTAC case C3L-00279, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.8 years (26,600 days).
Specimen C3L-00279-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60125baa-44ae-4c17-883f-a7b60e33d1b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00279-31 (Blood Derived Normal), aliquot CPT0081730001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b468557c-2ab6-4730-b6ac-28f22306cb58

The open-access MAF lists 795 somatic variants for this specimen: 556 protein-altering or splice-affecting, 151 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 479, Silent 151, Intron 43, Nonsense Mutation 32, Frame Shift Del 20, Splice Site 15, RNA 13, 3'UTR 12, 5'UTR 9, 5'Flank 8, Splice Region 6, Frame Shift Ins 4.

Variants (750 of 795; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 48/332 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 87/603 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as COSV50966965; called by muse, mutect2, varscan2
- ABCC9 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53963239; called by muse, varscan2
- ABCD2 | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs150810572; called by muse, mutect2, varscan2
- ADAMTS10 | c.2281C>A p.P761T | Missense Mutation (SNP) | VAF 60/347 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.246); catalogued as COSV54352470; called by muse, mutect2, varscan2
- ADGRG4 | c.6598G>T p.V2200L | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs965435331; called by muse, mutect2
- ADSS2 | c.790+1G>T p.X264_splice | Splice Site (SNP) | VAF 20/110 reads (18%) | catalogued as COSV100836920; called by muse, mutect2, varscan2
- AFF2 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.361); catalogued as COSV60677148; called by muse, mutect2
- AFF3 | c.2371G>T p.A791S | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.313); catalogued as rs200976815, COSV57846294; called by muse, mutect2, varscan2
- AGO1 | c.2135G>T p.R712L | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64595681; called by muse, mutect2
- AHNAK | c.16577G>C p.G5526A | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as COSV99948917; called by muse, mutect2, varscan2
- ANLN | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1312873978; called by muse, mutect2, varscan2
- APLP1 | c.698del p.P233Rfs*5 | Frame Shift Del (DEL) | VAF 17/163 reads (10%) | catalogued as rs1407940597; called by mutect2, pindel, varscan2
- APOB | c.3676G>A p.V1226M | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs138681343, COSV99266086; called by muse, mutect2, varscan2
- APOOL | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV64271625; called by muse, mutect2
- ASPM | c.6247A>G p.T2083A | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1202976470; called by muse, mutect2, varscan2
- ASTN1 | c.2632C>A p.Q878K | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV56063714, COSV99920359; called by muse, mutect2, varscan2
- AXDND1 | c.2891A>C p.E964A | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV62646684; called by muse, mutect2, varscan2
- BMPER | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 72/573 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV51823353; called by muse, mutect2, varscan2
- BPIFA3 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.195); catalogued as rs201399371; called by muse, mutect2, varscan2
- CASR | c.1030C>A p.H344N | Missense Mutation (SNP) | VAF 55/475 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56135195; called by muse, mutect2, varscan2
- CCDC27 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 21/242 reads (9%) | catalogued as rs762081181, COSV53900800; called by muse, mutect2
- CCSER1 | c.2297G>C p.R766P | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV61460135, COSV61466609; called by muse, mutect2, varscan2
- CD300LG | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as rs1387891856, COSV53224748; called by muse, varscan2
- CDH23 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as rs1212720284; called by muse, mutect2
- CFAP91 | c.1220C>A p.S407* | Nonsense Mutation (SNP) | VAF 31/193 reads (16%) | catalogued as rs773473514; called by muse, mutect2, varscan2
- CHODL | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs146669901; called by muse, mutect2
- CLCN1 | c.595C>A p.R199S | Missense Mutation (SNP) | VAF 68/545 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58372528; called by muse, mutect2, varscan2
- COL28A1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs371960243; called by muse, mutect2, varscan2
- COL9A1 | c.478C>A p.L160M | Missense Mutation (SNP) | VAF 49/430 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV61836588; called by muse, mutect2, varscan2
- CRYBA2 | c.448T>A p.W150R | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770881949; called by muse, mutect2, varscan2
- CT47B1 | c.709A>T p.T237S | Missense Mutation (SNP) | VAF 42/556 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.135); catalogued as rs752821345; called by muse, mutect2
- CXorf56 | c.344C>T p.T115M (on ENST00000536133 / NM_001170570.2; = p.T129M on NM_022101.4) | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as rs753049409, COSV100233460; called by muse, mutect2
- CYP4B1 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417831392; called by muse, mutect2, varscan2
- DACH2 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 20/170 reads (12%) | catalogued as rs1261647014, COSV100914126; called by muse, mutect2, varscan2
- DCHS1 | c.5432G>A p.R1811Q | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs753758536; called by muse, mutect2, varscan2
- DCHS1 | c.5065G>T p.V1689F | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV55042289; called by muse, mutect2, varscan2
- DCLK1 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs766765628, COSV99713539; called by muse, mutect2, varscan2
- DDB1 | c.1381G>T p.G461C | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV57103595; called by muse, mutect2
- DEGS2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs746617525; called by muse, mutect2, varscan2
- DSCAM | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 38/516 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV68029694; called by muse, mutect2
- DSE | c.1615G>T p.G539* | Nonsense Mutation (SNP) | VAF 22/246 reads (9%) | catalogued as COSV59067385; called by muse, mutect2
- DSP | c.7843G>A p.E2615K | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1221504284; called by muse, mutect2, varscan2
- DTNB | c.1660G>A p.G554S | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs202036284; called by muse, mutect2, varscan2
- DYDC1 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1429997652; called by muse, mutect2
- EDN3 | c.585del p.K196Rfs*13 (on ENST00000337938 / NM_001302455.2; = p.K196Rfs*2 on NM_207032.3) | Frame Shift Del (DEL) | VAF 50/519 reads (10%) | catalogued as COSV100284817; called by mutect2, pindel
- ELFN1 | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70035105; called by muse, mutect2, varscan2
- EPB41L2 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV100440573, COSV61355168; called by muse, mutect2
- EPB41L3 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs150101312; called by muse, mutect2, varscan2
- EPHA3 | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60732972; called by muse, mutect2, varscan2
- EPHA6 | c.1918G>T p.G640* (on ENST00000389672 / NM_001080448.3; = p.G32* on NM_173655.4) | Nonsense Mutation (SNP) | VAF 22/218 reads (10%) | catalogued as COSV101062384; called by muse, mutect2
- EPHB2 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as rs1444928620, COSV65860701; called by muse, mutect2, varscan2
- EYS | c.3317C>A p.P1106Q | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as CD140523; called by muse, mutect2, varscan2
- EYS | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100675679; called by muse, mutect2, varscan2
- EYS | c.704G>T p.W235L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as CM153010, COSV100675934; called by muse, mutect2
- FAM47B | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.645); catalogued as rs772809450, COSV61453403; called by muse, mutect2
- FANCG | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 74/822 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as rs372234656, COSV100734071; called by muse, mutect2
- FAT4 | c.13548del p.V4517Sfs*9 | Frame Shift Del (DEL) | VAF 50/433 reads (12%) | catalogued as COSV58710058; called by pindel, varscan2
- FBN2 | c.7422C>A p.C2474* | Nonsense Mutation (SNP) | VAF 85/531 reads (16%) | catalogued as COSV52542835; called by muse, mutect2, varscan2
- FCER1A | c.590-2A>T p.X197_splice | Splice Site (SNP) | VAF 27/115 reads (23%) | catalogued as rs780188505; called by muse, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIGNL1 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63554050, COSV63554065; called by muse, mutect2, varscan2
- FMN2 | c.806C>A p.T269N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs759794039; called by muse, mutect2, varscan2
- GABRG1 | c.238C>A p.R80S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54951118; called by muse, varscan2
- GIMAP6 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV61032837; called by muse, mutect2, varscan2
- GJA1 | c.836C>A p.S279* | Nonsense Mutation (SNP) | VAF 70/651 reads (11%) | catalogued as COSV56997529; called by muse, mutect2, varscan2
- GLI1 | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as COSV57357411; called by muse, varscan2
- GLUD2 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 40/520 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs1372295798; called by muse, mutect2
- GPBP1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs1185173574; called by muse, mutect2, varscan2
- GPI | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 48/389 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.164); catalogued as COSV100731374; called by muse, mutect2, varscan2
- GPR148 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV59308399; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 25/157 reads (16%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GYPE | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100679312; called by muse, mutect2, varscan2
- HAO1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV101113263; called by muse, mutect2
- HCN1 | c.1551C>G p.H517Q | Missense Mutation (SNP) | VAF 56/499 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100302170, COSV57494940; called by muse, mutect2, varscan2
- HEYL | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs367972512, COSV65721461; called by muse, mutect2
- HOXD13 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101184239; called by muse, varscan2
- HTR3A | c.36G>T p.L12F | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.272); catalogued as rs781487034; called by muse, mutect2, varscan2
- HYDIN | c.7414A>G p.M2472V | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs996068459; called by muse, mutect2, varscan2
- IDS | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as CD931006; called by muse, mutect2
- IGHE | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555456704; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 47/956 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756066868; called by muse, mutect2
- IGHV4-59 | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 53/690 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as rs782763389; called by muse, mutect2
- IMPG2 | c.2680C>A p.Q894K | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as rs1381004876; called by muse, mutect2, varscan2
- INPPL1 | c.3566A>T p.Q1189L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99996088; called by muse, mutect2, varscan2
- INSRR | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs1442419406; called by muse, mutect2, varscan2
- IRX2 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV100121901, COSV57412154; called by muse, mutect2, varscan2
- ISLR | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.602); catalogued as COSV51433111; called by muse, mutect2, varscan2
- KCNA5 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.375); catalogued as rs1020769441, COSV99363713; called by muse, mutect2, varscan2
- KRT34 | c.1111C>A p.R371S | Missense Mutation (SNP) | VAF 66/530 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67449832, COSV67450639; called by muse, mutect2, varscan2
- LAMA2 | c.8270C>T p.P2757L | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs768006670; called by muse, mutect2
- LMNTD2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99530880; called by muse, mutect2, varscan2
- LMX1B | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV62738903; called by muse, mutect2
- LRP1B | c.3440C>T p.T1147I | Missense Mutation (SNP) | VAF 38/331 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV67221987; called by muse, mutect2, varscan2
- MAGEB6 | c.195G>T p.Q65H | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV66872576, COSV66872641; called by muse, mutect2
- MOS | c.384del p.A129Qfs*6 | Frame Shift Del (DEL) | VAF 17/175 reads (10%) | catalogued as COSV61336722; called by mutect2, pindel
- MRPS12 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); catalogued as rs775990656; called by muse, mutect2, varscan2
- MYL7 | c.118-6C>A | Splice Region (SNP) | VAF 17/118 reads (14%) | catalogued as rs1454089264; called by muse, mutect2, varscan2
- MYLK | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 67/496 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as rs1560145846, COSV100658586; called by muse, mutect2, varscan2
- MYO9B | c.1519G>T p.V507L | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs200137248; called by muse, mutect2, varscan2
- MYOC | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 151/781 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM981347; called by muse, mutect2, varscan2
- MYRF | c.3362G>A p.R1121Q (on ENST00000278836 / NM_001127392.3; = p.R1081Q on NM_013279.4) | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs755995836; called by muse, mutect2
- NAP1L1 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53876621; called by muse, mutect2, varscan2
- NCOA7 | c.2330G>C p.R777P | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as rs756190152; called by muse, mutect2, varscan2
- NEXMIF | c.3202C>T p.L1068F | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1556016358; ClinVar: uncertain significance; called by muse, mutect2
- NKX2-2 | c.436C>A p.R146S | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65819292; called by muse, mutect2
- NLRP3 | c.2880del p.T961Hfs*3 | Frame Shift Del (DEL) | VAF 77/623 reads (12%) | catalogued as COSV100276658; called by pindel, varscan2
- NLRP7 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408512474; called by muse, mutect2
- OLFML2A | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs747350022, COSV99992611; called by muse, mutect2
- OR1J1 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.117); catalogued as COSV52237281; called by muse, mutect2
- OR2M5 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 91/489 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV63546597; called by muse, mutect2, varscan2
- OR2V2 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60315091, COSV60315740; called by muse, mutect2, varscan2
- OR2V2 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752306634, COSV100080292; called by muse, mutect2, varscan2
- OR4K1 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs139885856; called by muse, mutect2, varscan2
- OR4M1 | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs778692665, COSV60064156; called by muse, mutect2, varscan2
- PAK5 | c.729C>A p.S243R | Missense Mutation (SNP) | VAF 48/394 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.953); catalogued as COSV62028487; called by muse, mutect2, varscan2
- PAPPA2 | c.1555C>A p.L519I | Missense Mutation (SNP) | VAF 68/405 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV62772192; called by muse, mutect2, varscan2
- PCDHB2 | c.1552C>A p.L518I | Missense Mutation (SNP) | VAF 112/896 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV50606889; called by muse, varscan2
- PCDHB3 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 120/981 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50564787; called by muse, varscan2
- PDCD1 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV57691394; called by muse, mutect2, varscan2
- PEX5L | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17853563, COSV99829313; called by muse, mutect2, varscan2
- PLEK | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV52251062; called by muse, mutect2, varscan2
- PLIN3 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149231262; called by muse, mutect2, varscan2
- PRAMEF2 | c.866+2T>G p.X289_splice | Splice Site (SNP) | VAF 44/294 reads (15%) | catalogued as COSV53578378; called by muse, mutect2, varscan2
- PRDM9 | c.842C>A p.T281K | Missense Mutation (SNP) | VAF 74/569 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV57003271; called by muse, mutect2, varscan2
- PSG5 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61655062; called by muse, mutect2, varscan2
- PSG8 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV60617294; called by muse, mutect2, varscan2
- PTPN7 | c.745C>A p.H249N (on ENST00000495688; = p.H288N on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100459649; called by muse, mutect2, varscan2
- RAB2A | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV52914674; called by muse, mutect2
- RADX | c.2265A>G p.I755M | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs373355432; called by muse, mutect2, varscan2
- RAG2 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 65/569 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100271275; called by muse, mutect2, varscan2
- RGS7 | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 73/422 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as COSV100471511; called by muse, mutect2, varscan2
- RGS7 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV58535529; called by mutect2, varscan2
- RNF157 | c.1122C>A p.N374K | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53947628; called by muse, mutect2, varscan2
- RPGRIP1 | c.114G>T p.L38F | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV52853376; called by muse, mutect2
- RPL3L | c.55C>A p.H19N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51908392; called by muse, mutect2, varscan2
- RTL3 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1403744066; called by muse, mutect2, varscan2
- SALL1 | c.3454C>G p.H1152D | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99174768, COSV99180282; called by muse, mutect2
- SCART1 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs1021940619; called by muse, mutect2, varscan2
- SEMA3E | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100320003; called by muse, varscan2
- SEMA4F | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV60285258; called by muse, mutect2, varscan2
- SEMA5A | c.2626G>T p.G876* | Nonsense Mutation (SNP) | VAF 24/187 reads (13%) | catalogued as COSV66805307; called by muse, mutect2, varscan2
- SEPHS1 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59260623; called by muse, mutect2
- SHROOM2 | c.3794G>A p.R1265Q | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs763923609; called by muse, mutect2, varscan2
- SIGLEC1 | c.32C>A p.A11D | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs1304746011; called by muse, mutect2
- SLC4A1 | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 73/501 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1427615024; called by muse, mutect2, varscan2
- SLC5A9 | c.1591C>A p.L531M | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52583774; called by muse, mutect2, varscan2
- SPATA31D1 | c.3227C>A p.T1076K | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.327); catalogued as COSV61197563; called by muse, mutect2
- SYT16 | c.1849A>T p.S617C | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101413618; called by muse, mutect2, varscan2
- SYT6 | c.1387G>T p.G463* (on ENST00000610222 / NM_001366225.1; = p.G378* on NM_205848.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/150 reads (13%) | catalogued as COSV65775796; called by muse, mutect2, varscan2
- TBC1D4 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV66491129; called by muse, mutect2, varscan2
- TEP1 | c.5561G>T p.G1854V | Missense Mutation (SNP) | VAF 54/475 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563213330; called by muse, mutect2, varscan2
- TGIF2LX | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 56/501 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs780908528; called by muse, mutect2, varscan2
- THSD7A | c.4696G>T p.D1566Y | Missense Mutation (SNP) | VAF 53/384 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV101349148; called by muse, mutect2, varscan2
- TIAM2 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs1031872527, COSV59692110; called by muse, mutect2
- TMEM132C | c.1212G>T p.Q404H | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59435436; called by muse, mutect2, varscan2
- TNNI3K | c.1890G>A p.W630* | Nonsense Mutation (SNP) | VAF 25/173 reads (14%) | catalogued as COSV58565069; called by muse, mutect2, varscan2
- TRIM29 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 72/566 reads (13%) | catalogued as COSV100531582; called by muse, mutect2, varscan2
- TRIM39 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 81/342 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.673); catalogued as COSV64955126; called by muse, mutect2, varscan2
- TRIML2 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.534); catalogued as COSV58714824; called by muse, mutect2, varscan2
- TSC2 | c.2697G>T p.R899S | Missense Mutation (SNP) | VAF 52/579 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs45517256, COSV54779106; ClinVar: not provided; called by muse, mutect2
- TTI1 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1449501877; called by muse, mutect2, varscan2
- UROD | c.850T>G p.W284G | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as CM091819; called by muse, mutect2, varscan2
- USH2A | c.8456C>A p.T2819N | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs894122981; called by muse, mutect2, varscan2
- USH2A | c.3518C>A p.S1173* | Nonsense Mutation (SNP) | VAF 79/602 reads (13%) | catalogued as CM1110190, COSV56379599, COSV56424086; called by muse, mutect2, varscan2
- WDR72 | c.2056C>A p.L686M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV64748855; called by muse, mutect2, varscan2
- ZAN | c.7404C>A p.C2468* | Nonsense Mutation (SNP) | VAF 29/197 reads (15%) | catalogued as COSV61806951; called by muse, mutect2, varscan2
- ZFHX4 | c.1975C>A p.L659M | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51498797; called by muse, mutect2, varscan2
- ZNF439 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.555); catalogued as rs1486482987, COSV58309337; called by muse, mutect2, varscan2
- ZNF560 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.239); catalogued as COSV56866162; called by muse, mutect2, varscan2
- ZNF560 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 37/223 reads (17%) | catalogued as rs1568452982; called by muse, mutect2, varscan2
- ZNF711 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.515); catalogued as rs1427911141, COSV52156083; called by muse, mutect2
- ABI3BP | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 28/248 reads (11%) | called by muse, mutect2, varscan2
- ACE2 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.808); called by muse, mutect2
- ACSL4 | c.769C>A p.P257T (on ENST00000340800 / NM_022977.2; = p.P216T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- ACTN2 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 124/656 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS10 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ADAMTS12 | c.3028A>T p.I1010F | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ADAMTS4 | c.1086A>T p.E362D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADCY2 | c.2298G>T p.M766I | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- ADGB | c.1915T>A p.C639S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.345); called by muse, varscan2
- ADGRA3 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ADGRF1 | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); called by muse, varscan2
- ADGRG4 | c.2030T>A p.V677E | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- ADHFE1 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- AGXT | c.368T>A p.V123E | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AGXT2 | c.692T>A p.V231D | Missense Mutation (SNP) | VAF 56/562 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- AIPL1 | c.720del p.L241* | Frame Shift Del (DEL) | VAF 44/340 reads (13%) | called by mutect2, pindel, varscan2
- ALDH1L1 | c.124del p.L42Wfs*53 | Frame Shift Del (DEL) | VAF 25/138 reads (18%) | called by mutect2, pindel
- ALMS1 | c.11055C>A p.S3685R | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AMER1 | c.3206_3207insT p.S1070Qfs*24 | Frame Shift Ins (INS) | VAF 9/94 reads (10%) | called by mutect2, pindel
- ANK2 | c.8779C>A p.P2927T | Missense Mutation (SNP) | VAF 57/737 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD6 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.077); called by muse, mutect2
- ANKS6 | c.1111G>T p.G371W | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APOBR | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- APOC4-APOC2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.04); called by muse, mutect2
- AQR | c.1961A>T p.N654I | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP40 | c.1861C>A p.P621T | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASPM | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 66/549 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASTN1 | c.2633A>G p.Q878R | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ASTN2 | c.3188G>T p.S1063I (on ENST00000313400 / NM_001365069.1; = p.S1012I on NM_014010.5) | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2
- ASXL3 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATG2B | c.4333G>T p.E1445* | Nonsense Mutation (SNP) | VAF 25/202 reads (12%) | called by muse, mutect2, varscan2
- ATG4B | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ATP13A2 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 60/490 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ATP1A3 | c.1754A>T p.N585I (on ENST00000545399 / NM_001256214.2; = p.N572I on NM_152296.5) | Missense Mutation (SNP) | VAF 102/465 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- ATP2B3 | c.3303G>T p.Q1101H | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ATP6V0D2 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AUTS2 | c.3569_3570del p.P1190Qfs*91 | Frame Shift Del (DEL) | VAF 18/115 reads (16%) | called by mutect2, pindel, varscan2
- BBS9 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 39/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- BCL11A | c.2008G>T p.G670W (on ENST00000335712 / NM_001365609.1; = p.G704W on NM_018014.4) | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCOR | c.3652T>C p.W1218R (on ENST00000378444 / NM_001123385.2; = p.W1184R on NM_017745.6) | Missense Mutation (SNP) | VAF 28/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BEND2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- BEX3 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- C10orf71 | c.2756C>A p.P919H | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); called by muse, mutect2
- C14orf180 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- C4orf50 | c.264G>C p.R88S (on ENST00000324058; = p.R1320S on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- C9 | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CADPS | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CANX | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CARD19 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARMIL2 | c.1334+1G>T p.X445_splice | Splice Site (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- CATSPERE | c.1705C>A p.H569N | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBLB | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 64/638 reads (10%) | called by muse, mutect2
- CCDC83 | c.979G>A p.D327N (on ENST00000342404 / NM_001286159.2; = p.D358N on NM_173556.5) | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- CCL3 | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CD177 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CDH3 | c.992A>T p.Q331L | Missense Mutation (SNP) | VAF 86/632 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK5RAP2 | c.3536A>T p.Y1179F | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CDK6 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 41/386 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEMIP2 | c.1980G>T p.M660I | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- CEP19 | c.243G>T p.L81F | Missense Mutation (SNP) | VAF 68/462 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CFP | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CHRM3 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 91/424 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CNTNAP5 | c.2094G>A p.W698* | Nonsense Mutation (SNP) | VAF 36/201 reads (18%) | called by muse, mutect2, varscan2
- COL14A1 | c.4A>G p.K2E | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL19A1 | c.980dup p.E329Rfs*5 | Frame Shift Ins (INS) | VAF 8/94 reads (9%) | called by mutect2, pindel
- COL1A2 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL3A1 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 65/527 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A4 | c.2319G>T p.R773S | Missense Mutation (SNP) | VAF 67/562 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL6A3 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- COL6A5 | c.4407T>A p.D1469E | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2
- CPQ | c.1242A>T p.Q414H | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CPS1 | c.3759G>T p.V1253= | Splice Region (SNP) | VAF 34/384 reads (9%) | called by muse, mutect2
- CPVL | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYBB1 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD3 | c.8673C>A p.F2891L (on ENST00000297405 / NM_001363185.1; = p.F2722L on NM_052900.3) | Missense Mutation (SNP) | VAF 54/465 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSMD3 | c.8290A>T p.T2764S (on ENST00000297405 / NM_001363185.1; = p.T2595S on NM_052900.3) | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CSN1S1 | c.361-2A>T p.X121_splice | Splice Site (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- CTNND2 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CUBN | c.8965A>T p.S2989C | Missense Mutation (SNP) | VAF 72/673 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- CYP46A1 | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DCAF17 | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 72/544 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DGKZ | c.1688C>T p.P563L (on ENST00000454345 / NM_001105540.2; = p.P375L on NM_003646.4) | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DHRS2 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX35 | c.1639A>T p.T547S | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH9 | c.4200C>A p.D1400E | Missense Mutation (SNP) | VAF 62/447 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DNAI3 | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMBP | c.4151C>T p.T1384I | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, mutect2
- DOCK2 | c.3559G>C p.D1187H | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- DSCAML1 | c.4814C>A p.T1605K (on ENST00000321322; = p.T1545K on NM_020693.4) | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG3 | c.2694C>G p.C898W | Missense Mutation (SNP) | VAF 48/396 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- DUSP2 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1I1 | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- DYNC2H1 | c.12793G>T p.E4265* | Nonsense Mutation (SNP) | VAF 24/234 reads (10%) | called by muse, mutect2, varscan2
- DYTN | c.381A>T p.R127= | Splice Region (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.3344A>T p.E1115V | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ELAVL1 | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- EPHA6 | c.3256C>A p.L1086M | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EPHB1 | c.1088G>T p.C363F | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERCC6L | c.3367C>A p.P1123T | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERO1B | c.902A>C p.K301T | Missense Mutation (SNP) | VAF 84/472 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- EVC | c.1274A>T p.Q425L | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EVX1 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 60/478 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EXOC2 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 39/221 reads (18%) | called by muse, mutect2, varscan2
- EXTL3 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 56/510 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- F8 | c.3236G>T p.R1079M | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- FAM71E2 | c.2554A>T p.R852W | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- FAM90A1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 44/853 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2
- FANCB | c.2417G>A p.R806K | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- FAP | c.1274A>G p.Y425C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBN2 | c.6382T>A p.C2128S | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FCGBP | c.12080G>T p.C4027F | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRLB | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- FLNC | c.7280C>A p.A2427E | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FOXA2 | c.1000G>T p.E334* (on ENST00000377115 / NM_153675.3; = p.E340* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- FRMD7 | c.1639C>A p.L547M | Missense Mutation (SNP) | VAF 42/686 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); called by muse, mutect2
- FXYD4 | c.148A>T p.I50F | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); called by muse, mutect2
- FXYD4 | c.149T>A p.I50N | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- GABRB1 | c.881G>T p.R294M | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GABRB1 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- GALNT16 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAR1 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GLG1 | c.2550A>T p.E850D | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.147); called by muse, varscan2
- GNAS | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 43/532 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2
- GNPTAB | c.3136-2A>G p.X1046_splice | Splice Site (SNP) | VAF 39/259 reads (15%) | called by muse, mutect2, varscan2
- GPR158 | c.2459C>A p.T820N | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- GREB1 | c.3859C>A p.P1287T | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- GREB1L | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA3 | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 149/988 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GRIN2A | c.4036C>A p.Q1346K | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.037); called by muse, mutect2
- GRM5 | c.1526C>A p.S509Y | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HCN4 | c.3432del p.I1145Sfs*36 | Frame Shift Del (DEL) | VAF 48/262 reads (18%) | called by mutect2, pindel, varscan2
- HECW1 | c.1982G>T p.S661I | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- HECW1 | c.2494C>A p.P832T | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HK3 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- HOXB1 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HTR2A | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- HTRA1 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 47/521 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- HTRA1 | c.1129A>G p.I377V | Missense Mutation (SNP) | VAF 37/505 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- HUWE1 | c.8315C>A p.P2772Q | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- IGSF1 | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); called by muse, mutect2
- IL6ST | c.1635T>A p.D545E | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INPP5F | c.1516del p.A506Pfs*17 | Frame Shift Del (DEL) | VAF 16/170 reads (9%) | called by mutect2, pindel
- IPO7 | c.1042-1G>A p.X348_splice | Splice Site (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- IQCE | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2
- IRAK1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.115); called by muse, mutect2
- ITGAX | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ITK | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPK1 | c.1155del p.H386Tfs*72 | Frame Shift Del (DEL) | VAF 24/168 reads (14%) | called by mutect2, pindel, varscan2
- ITSN2 | c.3356G>A p.S1119N | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- JPH2 | c.730A>T p.S244C | Missense Mutation (SNP) | VAF 69/493 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JPH4 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- KCNG1 | c.989C>A p.A330E | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- KCNMA1 | c.4del p.A2Qfs*24 | Frame Shift Del (DEL) | VAF 6/80 reads (8%) | called by mutect2, pindel
- KCNQ2 | c.2464G>T p.A822S (on ENST00000359125 / NM_172107.4; = p.A794S on NM_004518.6) | Missense Mutation (SNP) | VAF 119/648 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- KCNT2 | c.3155T>A p.L1052H | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- KCTD16 | c.212del p.G71Efs*36 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.5612G>T p.G1871V | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- KIF16B | c.2876A>T p.Y959F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- KIFC2 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT34 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2
- LRRC7 | c.269A>T p.Y90F (on ENST00000651989 / NM_001370785.2; = p.Y57F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LY75 | c.3379G>C p.A1127P | Missense Mutation (SNP) | VAF 73/544 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAFA | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MAGEA6 | c.332G>C p.R111T | Missense Mutation (SNP) | VAF 58/576 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- MAGED1 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2
- MAGEL2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- MAML3 | c.3031G>T p.V1011L | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAN1C1 | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MAP2 | c.5298G>C p.E1766D | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- MAP3K19 | c.3792G>T p.K1264N | Missense Mutation (SNP) | VAF 58/449 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K5 | c.2068A>T p.T690S | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.121); called by muse, mutect2
- MAPKAPK5 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- MARK2 | c.874A>G p.R292G | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED25 | c.725A>T p.K242M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MFGE8 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 51/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MFGE8 | c.989G>C p.W330S | Missense Mutation (SNP) | VAF 56/373 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MGAM2 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MMRN1 | c.1727A>T p.N576I | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- MORC4 | c.2039C>A p.T680N | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH2B | c.2299C>A p.Q767K | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTCH2 | c.324T>A p.N108K | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTMR11 | c.227G>A p.R76K (on ENST00000439741 / NM_001145862.2; = p.X4_splice on NM_181873.3) | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MUC16 | c.24334C>A p.Q8112K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.3713C>T p.T1238I | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC17 | c.8638C>A p.P2880T | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MYH14 | c.5180G>T p.R1727L | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MYL7 | c.118-7C>T | Splice Region (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- MYO3A | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); called by muse, mutect2
- NADSYN1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAT10 | c.1858G>T p.G620C | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2
- NEFM | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- NFASC | c.1286C>A p.P429Q (on ENST00000339876 / NM_001378329.1; = p.P440Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- NHSL2 | c.259G>T p.G87W (on ENST00000510661; = p.G453W on NM_001013627.2) | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NLRP1 | c.2969G>C p.S990T | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP6 | c.1409T>C p.L470P | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPAS1 | c.1664A>C p.H555P | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); called by muse, mutect2
- NPAS4 | c.1740C>A p.S580R | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- NPR1 | c.2367G>T p.Q789H | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NPR3 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- NRCAM | c.3703A>G p.K1235E (on ENST00000379028 / NM_001371124.1; = p.K1114E on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NRG1 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); called by muse, mutect2
- NTN3 | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- NTNG1 | c.532T>A p.Y178N | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTS | c.215C>G p.A72G | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- NUGGC | c.920del p.K307Rfs*8 | Frame Shift Del (DEL) | VAF 16/179 reads (9%) | called by mutect2, pindel
- NUP58 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OR10H2 | c.740T>A p.I247N | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OR13C2 | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- OR13C5 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2
- OR2M3 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T1 | c.713C>G p.A238G | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- OR4Q3 | c.626T>G p.I209R | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- OR51B5 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2
- OR51L1 | c.387C>A p.C129* | Nonsense Mutation (SNP) | VAF 41/293 reads (14%) | called by muse, mutect2, varscan2
- OR56A3 | c.570A>T p.R190S | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OR56A4 | c.1022C>G p.A341G | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5B12 | c.567C>A p.D189E | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); called by muse, mutect2
- OR5F1 | c.493A>T p.S165C | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- OR8D2 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OSMR | c.320G>C p.C107S | Missense Mutation (SNP) | VAF 68/405 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OTOG | c.5236A>T p.M1746L | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- PABPN1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 54/366 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PAX1 | c.469A>T p.T157S | Missense Mutation (SNP) | VAF 32/425 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- PCDH10 | c.1184G>T p.C395F | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- PCDH11X | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 66/659 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH7 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB12 | c.2152A>T p.R718W | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PCDHGB2 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PCLO | c.11014G>A p.A3672T | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PCSK5 | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDE10A | c.423del p.I142* | Frame Shift Del (DEL) | VAF 17/165 reads (10%) | called by mutect2, pindel
- PDE3A | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PDGFRA | c.280C>A p.H94N | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDGFRA | c.2435A>T p.K812I | Missense Mutation (SNP) | VAF 54/419 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDGFRB | c.3145C>A p.L1049M | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDHX | c.1315A>T p.I439F | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX26 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 66/528 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHLDB2 | c.2602G>T p.V868L (on ENST00000393925 / NM_001134439.2; = p.V825L on NM_145753.2) | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIEZO2 | c.5258C>G p.T1753R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); called by muse, mutect2
- PIK3C2A | c.3550G>T p.V1184L | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3R5 | c.412+1G>T p.X138_splice | Splice Site (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3229+1G>T p.X1077_splice | Splice Site (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- PLCL1 | c.2887G>T p.V963L | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PMPCA | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, varscan2
- PNCK | c.911C>G p.T304S (on ENST00000340888 / NM_001366975.1; = p.T387S on NM_001039582.3) | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- POLR3A | c.2234del p.E745Gfs*7 | Frame Shift Del (DEL) | VAF 34/434 reads (8%) | called by mutect2, pindel
- PPP1R3A | c.1165dup p.Y389Lfs*4 | Frame Shift Ins (INS) | VAF 19/209 reads (9%) | called by mutect2, pindel
- PPP6R1 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PRDM9 | c.299_300insG p.V101Sfs*14 | Frame Shift Ins (INS) | VAF 83/573 reads (14%) | called by mutect2, pindel, varscan2
- PRKDC | c.10570A>T p.N3524Y | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PRODH2 | c.702G>C p.Q234H (on ENST00000301175; = p.Q158H on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS41 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PTK2B | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- PTPDC1 | c.1257G>C p.L419F (on ENST00000375360 / NM_177995.3; = p.L471F on NM_152422.4) | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN5 | c.863A>T p.E288V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PTPN7 | c.332C>A p.P111H (on ENST00000495688; = p.P150H on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- PTPRJ | c.2825C>A p.P942H | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- PYGL | c.2056G>T p.G686W | Missense Mutation (SNP) | VAF 50/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PZP | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- QSER1 | c.1684G>T p.D562Y (on ENST00000399302; = p.D691Y on NM_001076786.3) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RAB3GAP2 | c.1055G>T p.W352L | Missense Mutation (SNP) | VAF 65/624 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- RAD51AP2 | c.2762A>G p.N921S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- RALGPS1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- RAPGEF4 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RECQL5 | c.799A>T p.R267W | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- RFX3 | c.1704G>T p.Q568H | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RGS12 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 23/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RGS20 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- RNF111 | c.2971C>T p.P991S (on ENST00000557998 / NM_001270530.1; = p.P983S on NM_017610.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RNF40 | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RPP40 | c.909A>C p.E303D | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RPS8 | c.277A>T p.T93S | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RSPH3 | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); called by muse, mutect2
- RSPO2 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RTL3 | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2
- RTL9 | c.1186G>T p.G396W | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RUFY3 | c.1262A>T p.Q421L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SAFB2 | c.2599_2615del p.D867Pfs*97 | Frame Shift Del (DEL) | VAF 20/168 reads (12%) | called by mutect2, pindel
- SBF2 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 64/468 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, varscan2
- SCFD1 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN10A | c.2468C>A p.P823H | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SEPTIN14 | c.312G>T p.Q104H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2
- SEPTIN4 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- SERBP1 | c.850G>T p.G284C (on ENST00000370995 / NM_001018067.2; = p.G263C on NM_015640.4) | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SERGEF | c.1204C>A p.L402M | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.365); called by muse, mutect2
- SETBP1 | c.2922C>A p.Y974* | Nonsense Mutation (SNP) | VAF 76/797 reads (10%) | called by muse, mutect2
- SFMBT2 | c.1063G>T p.G355W | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SI | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SIGLEC10 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SIPA1L3 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); called by muse, varscan2
- SLC17A1 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A8 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SLC36A1 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC4A10 | c.2586G>T p.M862I (on ENST00000446997 / NM_001354461.2; = p.M832I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SLC7A13 | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SLC8A1 | c.2229C>G p.S743R | Missense Mutation (SNP) | VAF 40/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC8A3 | c.1490G>C p.G497A | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); called by muse, mutect2
- SLC9A2 | c.290-2A>T p.X97_splice | Splice Site (SNP) | VAF 16/96 reads (17%) | called by muse, varscan2
- SLITRK4 | c.1532T>G p.L511R | Missense Mutation (SNP) | VAF 35/441 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLTM | c.2626A>T p.N876Y | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SMARCA5 | c.2924A>T p.Q975L | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- SMOC2 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.315); called by muse, varscan2
- SMR3B | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 15/283 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, mutect2
- SNX3 | c.272C>A p.P91Q | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- SOGA1 | c.2461A>T p.K821* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- SPAG17 | c.3101C>A p.S1034* | Nonsense Mutation (SNP) | VAF 41/230 reads (18%) | called by muse, varscan2
- SPANXN5 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA31A1 | c.3890A>G p.N1297S | Missense Mutation (SNP) | VAF 47/936 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.088); called by muse, mutect2
- SPATA31D1 | c.3636G>T p.Q1212H | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.332); called by muse, mutect2
- SRCAP | c.7267A>T p.T2423S | Missense Mutation (SNP) | VAF 71/410 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SRCIN1 | c.3487G>T p.A1163S (on ENST00000621492; = p.A1129S on NM_025248.3) | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SS18 | c.880G>T p.G294C (on ENST00000415083 / NM_001007559.3; = p.G294* on NM_005637.3) | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ST8SIA5 | c.764C>A p.T255N | Missense Mutation (SNP) | VAF 35/280 reads (13%) | PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STEAP2 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- STIM2 | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SUN5 | c.862A>T p.S288C | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2
- SYDE2 | c.2815A>T p.T939S | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SYN2 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SYNE2 | c.20440A>T p.T6814S | Missense Mutation (SNP) | VAF 44/452 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TACR3 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 77/502 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- TAF1 | c.2078G>T p.G693V (on ENST00000373790 / NM_138923.4; = p.G714V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TBATA | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2
- TBRG1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- TECTA | c.5343G>T p.R1781S | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEX13C | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- TEX15 | c.2347C>A p.P783T (on ENST00000256246; = p.P1166T on NM_001350162.2) | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.106); called by muse, mutect2
- TG | c.7441C>A p.P2481T | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TGFBR2 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TGFBR3 | c.384+1G>T p.X128_splice | Splice Site (SNP) | VAF 55/336 reads (16%) | called by muse, mutect2, varscan2
- TIMP1 | c.390C>G p.S130R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- TLR4 | c.1500C>A p.F500L (on ENST00000355622 / NM_138554.5; = p.F460L on NM_003266.4) | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- TMEFF2 | c.289A>T p.N97Y | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2
- TMEM132C | c.1213G>T p.V405L | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TMEM132D | c.2614T>A p.L872I | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMEM178B | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM26 | c.163A>C p.K55Q | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPR | c.7064G>T p.G2355V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM49 | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2
- TRIM51GP | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.312); called by muse, mutect2
- TRMT1L | c.780-1G>A p.X260_splice | Splice Site (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- TRMT6 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 64/497 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, varscan2
- TRO | c.4000A>G p.I1334V | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.946); called by muse, mutect2
- TTC5 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TTN | c.53515C>A p.P17839T (on ENST00000591111; = p.P10415T on NM_003319.4) | Missense Mutation (SNP) | VAF 40/298 reads (13%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.45408T>A p.N15136K (on ENST00000591111; = p.N7712K on NM_003319.4) | Missense Mutation (SNP) | VAF 30/228 reads (13%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBB8 | c.277+4A>T | Splice Region (SNP) | VAF 41/348 reads (12%) | called by muse, mutect2, varscan2
- U2SURP | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- UBE2G2 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBXN1 | c.60-4C>T | Splice Region (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- UMOD | c.1481del p.G494Afs*10 | Frame Shift Del (DEL) | VAF 48/508 reads (9%) | called by mutect2, pindel
- UNC5C | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- UNC80 | c.8353G>T p.G2785W | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UPRT | c.726C>A p.S242R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- URB1 | c.5770A>T p.I1924F | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- UROC1 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 86/523 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- VAV3 | c.1903C>A p.L635M | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- VWA5A | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASHC2A | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 34/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WRN | c.2449-1G>T p.X817_splice | Splice Site (SNP) | VAF 40/300 reads (13%) | called by muse, mutect2, varscan2
- XIRP2 | c.152T>A p.V51E | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- XIRP2 | c.2863C>A p.L955I (on ENST00000628543; = p.L1130I on NM_152381.6) | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- XPNPEP2 | c.1784C>A p.P595H | Missense Mutation (SNP) | VAF 42/407 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YPEL5 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 47/420 reads (11%) | called by muse, mutect2, varscan2
- YWHAH | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ZC3H6 | c.2428G>T p.A810S | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC4H2 | c.426G>T p.W142C | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZFPM2 | c.2933C>A p.A978D | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZIC1 | c.585C>G p.H195Q | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ZNF185 | c.1716-2A>T p.X572_splice | Splice Site (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- ZNF197 | c.1732A>T p.S578C | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZNF430 | c.881G>T p.C294F | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF521 | c.41-1G>T p.X14_splice | Splice Site (SNP) | VAF 46/239 reads (19%) | called by muse, mutect2, varscan2
- ZNF536 | c.1931A>T p.H644L | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF543 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF568 | c.1765A>T p.R589* | Nonsense Mutation (SNP) | VAF 39/283 reads (14%) | called by muse, mutect2, varscan2
- ZNF607 | c.1692G>T p.K564N | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ZNF679 | c.651C>A p.C217* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- ZNF683 | c.40A>T p.R14W | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ZNF804A | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.026); called by muse, mutect2
- ZNF804B | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF831 | c.508A>T p.R170W | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF831 | c.4078T>G p.C1360G | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2
- ZP4 | c.770A>C p.N257T | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ABCC11 | c.2889G>T p.L963= | Silent (SNP) | VAF 51/321 reads (16%) | called by muse, mutect2, varscan2
- ACE2 | c.483G>A p.R161= | Silent (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- ACER1 | c.747C>A p.P249= | Silent (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- ADAM11 | c.1767C>T p.V589= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV52345786; called by muse, mutect2, varscan2
- ADAMTS12 | c.2907C>T p.V969= | Silent (SNP) | VAF 64/523 reads (12%) | catalogued as rs1270055582; called by muse, mutect2
- ADGRA3 | c.3732C>T p.S1244= | Silent (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- ADGRB1 | c.267G>T p.A89= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs780978178; called by muse, mutect2, varscan2
- AGRN | c.207G>T p.R69= | Silent (SNP) | VAF 39/382 reads (10%) | called by muse, mutect2, varscan2
- ALG9 | c.1428C>T p.P476= (on ENST00000614444 / NM_001352418.1; = p.P483= on NM_024740.2) | Silent (SNP) | VAF 43/389 reads (11%) | called by muse, mutect2, varscan2
- ANGPTL2 | c.591C>A p.I197= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as COSV99401324; called by muse, mutect2, varscan2
- ANKRD33B | c.642G>A p.A214= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs976273133, COSV56976331; called by muse, mutect2
- ANKRD35 | c.741G>T p.R247= | Silent (SNP) | VAF 18/98 reads (18%) | called by muse, varscan2
- APLNR | c.729G>C p.R243= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- ARMCX2 | c.1443G>T p.L481= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as COSV57529397; called by muse, mutect2
- ARX | c.825C>A p.A275= | Silent (SNP) | VAF 22/266 reads (8%) | catalogued as rs922800521; called by muse, mutect2
- ATP10D | c.114C>T p.R38= | Silent (SNP) | VAF 17/344 reads (5%) | called by muse, mutect2
- AUH | c.489A>T p.A163= | Silent (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- BCHE | c.576G>T p.G192= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as rs537314243, COSV100013075; called by muse, mutect2, varscan2
- BCOR | c.4932C>A p.T1644= (on ENST00000378444 / NM_001123385.2; = p.T1610= on NM_017745.6) | Silent (SNP) | VAF 35/378 reads (9%) | called by muse, mutect2
- BCORL1 | c.876A>T p.S292= | Silent (SNP) | VAF 50/359 reads (14%) | called by muse, mutect2, varscan2
- BCR | c.3750G>T p.L1250= | Silent (SNP) | VAF 31/269 reads (12%) | called by muse, mutect2, varscan2
- BDKRB1 | c.102C>T p.D34= | Silent (SNP) | VAF 39/258 reads (15%) | called by muse, mutect2, varscan2
- BTBD17 | c.232C>A p.R78= | Silent (SNP) | VAF 51/378 reads (13%) | catalogued as COSV64730416; called by muse, mutect2, varscan2
- BTNL2 | c.579C>A p.I193= | Silent (SNP) | VAF 113/570 reads (20%) | catalogued as COSV100896204; called by muse, mutect2, varscan2
- BTNL8 | c.546C>T p.N182= | Silent (SNP) | VAF 45/357 reads (13%) | called by muse, mutect2, varscan2
- CADM2 | c.579C>T p.D193= (on ENST00000407528 / NM_001167674.2; = p.D195= on NM_153184.4) | Silent (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
- CASR | c.1029C>A p.V343= | Silent (SNP) | VAF 52/466 reads (11%) | called by muse, mutect2, varscan2
- CBX2 | c.1425G>T p.S475= | Silent (SNP) | VAF 41/324 reads (13%) | called by muse, mutect2, varscan2
- CCDC168 | c.15447G>A p.A5149= | Silent (SNP) | VAF 46/277 reads (17%) | catalogued as rs111548184, COSV59420787; called by muse, mutect2, varscan2
- CCKBR | c.141C>A p.A47= | Silent (SNP) | VAF 29/211 reads (14%) | catalogued as COSV58101590; called by muse, mutect2, varscan2
- CDH17 | c.222G>T p.R74= | Silent (SNP) | VAF 25/256 reads (10%) | catalogued as COSV50325660; called by muse, mutect2
- CDH23 | c.1701G>T p.V567= | Silent (SNP) | VAF 17/278 reads (6%) | called by muse, mutect2
- CFAP20DC | c.738A>T p.T246= (on ENST00000482387 / NM_001351530.2; = p.T121= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- CNGB1 | c.375G>T p.P125= | Silent (SNP) | VAF 56/570 reads (10%) | catalogued as COSV51904688; called by muse, mutect2, varscan2
- COL12A1 | c.5427C>A p.V1809= | Silent (SNP) | VAF 17/209 reads (8%) | called by muse, mutect2
- COL4A2 | c.612G>T p.V204= | Silent (SNP) | VAF 55/438 reads (13%) | called by muse, mutect2, varscan2
- COQ9 | c.739C>T p.L247= | Silent (SNP) | VAF 47/517 reads (9%) | called by muse, mutect2
- CPA5 | c.324G>A p.K108= | Silent (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- CPQ | c.768A>T p.L256= | Silent (SNP) | VAF 52/393 reads (13%) | called by muse, mutect2, varscan2
- CSHL1 | c.57C>A p.P19= | Silent (SNP) | VAF 84/679 reads (12%) | called by muse, mutect2, varscan2
- DACT1 | c.2083C>A p.R695= | Silent (SNP) | VAF 15/203 reads (7%) | called by muse, mutect2
- DCHS1 | c.7632T>A p.A2544= | Silent (SNP) | VAF 31/227 reads (14%) | called by muse, mutect2, varscan2
- DCHS1 | c.819T>A p.P273= | Silent (SNP) | VAF 52/350 reads (15%) | called by muse, mutect2, varscan2
- DECR2 | c.372C>T p.A124= | Silent (SNP) | VAF 34/265 reads (13%) | called by muse, mutect2, varscan2
- DENND1C | c.90C>A p.P30= | Silent (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- DHTKD1 | c.360C>G p.V120= | Silent (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- DNAH12 | c.6051A>T p.P2017= (on ENST00000351747; = p.P2036= on NM_001366028.2) | Silent (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.11019A>G p.P3673= | Silent (SNP) | VAF 65/471 reads (14%) | called by muse, mutect2, varscan2
- DYRK1B | c.114G>T p.R38= | Silent (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- ECI2 | c.921A>T p.T307= (on ENST00000380118 / NM_206836.3; = p.T277= on NM_006117.2) | Silent (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- ELF4 | c.957C>T p.A319= | Silent (SNP) | VAF 19/213 reads (9%) | called by muse, mutect2
- EPB41L2 | c.1062C>T p.G354= | Silent (SNP) | VAF 25/344 reads (7%) | catalogued as rs771274724; called by muse, mutect2
- EPPK1 | c.5721C>T p.T1907= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as rs1554659505; called by muse, mutect2, varscan2
- EVC2 | c.1050A>T p.S350= | Silent (SNP) | VAF 76/503 reads (15%) | called by muse, mutect2, varscan2
- FAM83D | c.36C>A p.P12= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- FASTKD1 | c.1866A>G p.T622= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- FBXW10 | c.696G>T p.R232= | Silent (SNP) | VAF 24/253 reads (9%) | called by muse, mutect2
- FER1L6 | c.2838T>C p.S946= | Silent (SNP) | VAF 28/286 reads (10%) | called by muse, mutect2
- FRYL | c.2970G>A p.L990= | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- FSIP2 | c.2394A>G p.T798= | Silent (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- FSTL5 | c.1593C>G p.S531= | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as COSV100055881; called by muse, mutect2, varscan2
- GJC1 | c.816G>A p.P272= | Silent (SNP) | VAF 32/258 reads (12%) | catalogued as rs539602139, COSV100395262; called by muse, mutect2, varscan2
- GPRC5B | c.342C>T p.I114= | Silent (SNP) | VAF 30/241 reads (12%) | catalogued as COSV56029077; called by muse, mutect2, varscan2
- GSN | c.2085G>T p.T695= | Silent (SNP) | VAF 58/676 reads (9%) | catalogued as COSV100375901, COSV57999543; called by muse, mutect2
- HDDC2 | c.339A>T p.L113= | Silent (SNP) | VAF 30/340 reads (9%) | catalogued as COSV100600272; called by muse, mutect2
- HEATR1 | c.3180G>A p.L1060= | Silent (SNP) | VAF 48/350 reads (14%) | called by muse, mutect2, varscan2
- IL2RA | c.132A>T p.G44= | Silent (SNP) | VAF 24/383 reads (6%) | called by muse, mutect2
- ITGAX | c.1350G>T p.T450= | Silent (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- JMJD6 | c.957G>A p.E319= | Silent (SNP) | VAF 30/203 reads (15%) | called by muse, mutect2, varscan2
- KCNS1 | c.372C>T p.H124= | Silent (SNP) | VAF 24/192 reads (13%) | catalogued as rs1237314686; called by muse, mutect2, varscan2
- KDM4E | c.718C>A p.R240= | Silent (SNP) | VAF 72/523 reads (14%) | catalogued as COSV71678337; called by muse, mutect2, varscan2
- KHDC1L | c.351C>T p.V117= | Silent (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- KIAA1549 | c.4485G>T p.P1495= | Silent (SNP) | VAF 20/157 reads (13%) | catalogued as COSV99651413, COSV99652174; called by muse, mutect2, varscan2
- KIF17 | c.2112G>T p.V704= | Silent (SNP) | VAF 50/398 reads (13%) | called by muse, mutect2, varscan2
- KIF5C | c.2463C>T p.N821= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs779885153; called by muse, mutect2, varscan2
- KRT23 | c.123C>A p.A41= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, varscan2
- KRTAP10-9 | c.618C>A p.S206= | Silent (SNP) | VAF 78/738 reads (11%) | called by muse, mutect2, varscan2
- L1CAM | c.3289C>A p.R1097= | Silent (SNP) | VAF 78/430 reads (18%) | catalogued as COSV62828807; called by muse, mutect2, varscan2
- L1CAM | c.60C>A p.I20= | Silent (SNP) | VAF 46/637 reads (7%) | catalogued as COSV62808395; called by muse, mutect2
- LHX2 | c.558G>T p.V186= | Silent (SNP) | VAF 19/211 reads (9%) | called by muse, mutect2
- LMOD2 | c.93G>A p.K31= | Silent (SNP) | VAF 57/441 reads (13%) | catalogued as rs1306818370; called by muse, mutect2, varscan2
- MAP3K14 | c.1011A>T p.L337= | Silent (SNP) | VAF 45/308 reads (15%) | called by muse, mutect2, varscan2
- MARK4 | c.1035G>T p.R345= | Silent (SNP) | VAF 34/226 reads (15%) | catalogued as COSV53462222; called by muse, mutect2, varscan2
- MISP | c.543G>T p.L181= | Silent (SNP) | VAF 49/244 reads (20%) | called by muse, mutect2, varscan2
- MS4A1 | c.300C>A p.L100= | Silent (SNP) | VAF 32/418 reads (8%) | catalogued as COSV61942109; called by muse, mutect2
- MUC16 | c.22860C>A p.T7620= | Silent (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- MXRA5 | c.6885T>A p.G2295= | Silent (SNP) | VAF 37/441 reads (8%) | called by muse, mutect2
- MYLK | c.2199C>A p.S733= | Silent (SNP) | VAF 58/388 reads (15%) | called by muse, mutect2, varscan2
- MYPOP | c.630G>T p.P210= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs747448325; called by muse, mutect2, varscan2
- NHSL1 | c.315G>T p.L105= | Silent (SNP) | VAF 36/249 reads (14%) | called by muse, mutect2, varscan2
- NLRP1 | c.3366G>T p.A1122= | Silent (SNP) | VAF 50/394 reads (13%) | called by muse, mutect2, varscan2
- NOSTRIN | c.591C>G p.T197= (on ENST00000317647 / NM_001039724.4; = p.T119= on NM_052946.3) | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV100473266; called by muse, mutect2, varscan2
- NOX1 | c.1650G>A p.L550= | Silent (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- OPCML | c.633C>A p.P211= | Silent (SNP) | VAF 23/199 reads (12%) | catalogued as COSV59409909; called by muse, mutect2, varscan2
- OPRD1 | c.132G>T p.S44= | Silent (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- OR10J3 | c.120C>A p.L40= | Silent (SNP) | VAF 41/403 reads (10%) | called by muse, mutect2, varscan2
- OR13F1 | c.213C>A p.I71= | Silent (SNP) | VAF 15/219 reads (7%) | catalogued as COSV58252085; called by muse, mutect2
- OR1J1 | c.522C>A p.I174= | Silent (SNP) | VAF 18/275 reads (7%) | called by muse, mutect2
- OR1K1 | c.354C>A p.A118= | Silent (SNP) | VAF 28/249 reads (11%) | called by muse, mutect2, varscan2
- OR52D1 | c.12C>A p.S4= | Silent (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- OR5M8 | c.786C>T p.P262= | Silent (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- OR6B2 | c.147C>A p.V49= | Silent (SNP) | VAF 46/421 reads (11%) | catalogued as rs776253431; called by muse, mutect2, varscan2
- OTOG | c.5235C>A p.P1745= | Silent (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2
- P3H1 | c.159G>T p.G53= | Silent (SNP) | VAF 66/402 reads (16%) | called by muse, mutect2, varscan2
- PCDH15 | c.4752G>A p.L1584= | Silent (SNP) | VAF 40/436 reads (9%) | catalogued as COSV57276437; called by muse, mutect2
- PCDHA3 | c.2295C>A p.P765= | Silent (SNP) | VAF 36/235 reads (15%) | called by muse, mutect2, varscan2
- PCLO | c.5685A>T p.P1895= | Silent (SNP) | VAF 20/174 reads (11%) | called by muse, mutect2, varscan2
- PDZD4 | c.1920C>A p.P640= | Silent (SNP) | VAF 30/260 reads (12%) | catalogued as rs375303161, COSV51247484, COSV99381525; called by muse, mutect2, varscan2
- PITPNM3 | c.1995G>T p.L665= | Silent (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2, varscan2
- PKHD1 | c.1632A>T p.A544= | Silent (SNP) | VAF 85/534 reads (16%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.7671G>C p.V2557= | Silent (SNP) | VAF 29/314 reads (9%) | called by muse, mutect2
- PLEK2 | c.477C>T p.F159= | Silent (SNP) | VAF 32/256 reads (13%) | catalogued as rs1404029615; called by muse, mutect2, varscan2
- PLEKHG5 | c.1341G>A p.R447= (on ENST00000400915 / NM_001042663.3; = p.R410= on NM_020631.6) | Silent (SNP) | VAF 20/188 reads (11%) | called by muse, mutect2
- PLXNA4 | c.1734C>A p.V578= | Silent (SNP) | VAF 33/250 reads (13%) | catalogued as COSV100322289; called by muse, mutect2, varscan2
- PLXNB3 | c.1503C>A p.T501= | Silent (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- POU3F4 | c.372C>A p.I124= | Silent (SNP) | VAF 26/286 reads (9%) | catalogued as COSV64537757; called by muse, mutect2
- PROX1 | c.1488A>T p.P496= | Silent (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- RAB33A | c.450C>A p.G150= | Silent (SNP) | VAF 36/446 reads (8%) | called by muse, mutect2
- RAB4B | c.253C>T p.L85= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV63825414; called by muse, mutect2
- RALGDS | c.921A>T p.V307= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- RBM10 | c.960G>T p.L320= | Silent (SNP) | VAF 36/424 reads (8%) | called by muse, mutect2
- SEC23B | c.1974T>A p.I658= | Silent (SNP) | VAF 19/301 reads (6%) | called by muse, mutect2
- SEMA5B | c.1596C>A p.R532= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs1323588046; called by muse, mutect2, varscan2
- SETBP1 | c.2280C>A p.A760= | Silent (SNP) | VAF 47/421 reads (11%) | catalogued as rs769433440; called by muse, mutect2, varscan2
- SIPA1L1 | c.168C>T p.P56= | Silent (SNP) | VAF 30/281 reads (11%) | called by muse, mutect2, varscan2
- SLC17A1 | c.258C>G p.S86= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV55080455; called by muse, mutect2
- SLC18B1 | c.780C>G p.L260= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- SLC22A18 | c.498C>T p.L166= | Silent (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- SNAP47 | c.999A>G p.P333= | Silent (SNP) | VAF 108/638 reads (17%) | called by muse, mutect2, varscan2
- SPEG | c.291C>A p.R97= | Silent (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- SPEG | c.5697C>T p.A1899= | Silent (SNP) | VAF 48/242 reads (20%) | called by muse, mutect2, varscan2
- SPTB | c.111C>T p.A37= | Silent (SNP) | VAF 63/626 reads (10%) | called by muse, mutect2
- SSTR4 | c.729G>A p.L243= | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- STAG3 | c.1620C>T p.S540= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs1369184415; called by muse, mutect2
- STX4 | c.855C>G p.V285= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- SUPT20HL1 | c.1215G>T p.V405= | Silent (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- THSD7A | c.3834C>A p.S1278= | Silent (SNP) | VAF 32/251 reads (13%) | called by muse, mutect2, varscan2
- TMC6 | c.1749G>T p.R583= | Silent (SNP) | VAF 76/635 reads (12%) | called by muse, mutect2, varscan2
- TMEM132D | c.841C>T p.L281= | Silent (SNP) | VAF 64/412 reads (16%) | called by muse, mutect2, varscan2
- TMPRSS11D | c.936C>A p.G312= | Silent (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- TRIM14 | c.675G>C p.T225= | Silent (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2, varscan2
- TRIM63 | c.954C>T p.A318= | Silent (SNP) | VAF 24/196 reads (12%) | called by muse, mutect2, varscan2
- TRIML1 | c.474C>A p.T158= | Silent (SNP) | VAF 27/232 reads (12%) | called by muse, mutect2, varscan2
- TRPM3 | c.1707G>T p.L569= (on ENST00000357533 / NM_001366142.2; = p.L402= on NM_020952.6) | Silent (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2
- TTC21A | c.1503G>T p.L501= | Silent (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.49092T>C p.T16364= (on ENST00000591111; = p.T8940= on NM_003319.4) | Silent (SNP) | VAF 26/206 reads (13%) | called by muse, mutect2, varscan2
- VCAN | c.9177A>G p.P3059= | Silent (SNP) | VAF 51/402 reads (13%) | called by muse, mutect2, varscan2
- VIM | c.957C>T p.Y319= | Silent (SNP) | VAF 53/555 reads (10%) | called by muse, mutect2
- WDR87 | c.8151T>C p.S2717= | Silent (SNP) | VAF 38/367 reads (10%) | called by muse, mutect2, varscan2
- ZNF284 | c.483C>T p.I161= | Silent (SNP) | VAF 65/344 reads (19%) | catalogued as COSV101399115; called by muse, mutect2, varscan2
- ZNF469 | c.1872G>A p.Q624= | Silent (SNP) | VAF 81/575 reads (14%) | catalogued as COSV71258968; called by muse, mutect2, varscan2
- ABCD4 | c.668+61G>T | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- AC008080.1 | n.502G>T | RNA (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
- AC099548.2 | n.1491G>T | RNA (SNP) | VAF 74/1207 reads (6%) | called by muse, mutect2
- AC100868.1 | c.152-2156G>T | Intron (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- AC100868.1 | c.152-2157G>T | Intron (SNP) | VAF 22/254 reads (9%) | called by muse, mutect2
- ACSF3 | c.*1316G>A | 3'UTR (SNP) | VAF 46/402 reads (11%) | catalogued as rs560746166; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83291G>T | Intron (SNP) | VAF 48/682 reads (7%) | catalogued as rs780928490; called by muse, mutect2
- AL353804.4 | chrX:73821073 C>G | 3'Flank (SNP) | VAF 46/412 reads (11%) | called by muse, mutect2, varscan2
- ALOX5AP | c.-56G>T | 5'UTR (SNP) | VAF 26/186 reads (14%) | called by muse, mutect2, varscan2
- AMN | c.1006+30C>T | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.1330G>T | RNA (SNP) | VAF 56/575 reads (10%) | called by muse, mutect2, varscan2
- AP000356.3 | n.746C>T | RNA (SNP) | VAF 86/512 reads (17%) | called by muse, varscan2
- AP000769.5 | chr11:65499541 G>T | 5'Flank (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- ARL13B | c.-30G>T | 5'UTR (SNP) | VAF 63/335 reads (19%) | called by muse, mutect2, varscan2
- B3GAT1 | c.-21T>C | 5'UTR (SNP) | VAF 19/232 reads (8%) | called by muse, mutect2
- BOD1P2 | n.434C>A | RNA (SNP) | VAF 20/82 reads (24%) | called by muse, varscan2
- BX682237.1 | chrX:155208937 G>T | 3'Flank (SNP) | VAF 24/300 reads (8%) | called by muse, mutect2
- C4orf50 | c.-1248C>A | 5'UTR (SNP) | VAF 34/224 reads (15%) | catalogued as rs939883257, COSV60691197; called by muse, mutect2, varscan2
- CA5B | c.143-1683G>C | Intron (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- CALD1 | c.71+23831C>A | Intron (SNP) | VAF 19/156 reads (12%) | catalogued as COSV62644931; called by muse, mutect2, varscan2
- CASK | c.1156-22G>T | Intron (SNP) | VAF 23/317 reads (7%) | called by muse, mutect2
- CCNB1IP1 | c.-37-3751G>T | Intron (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- CDH6 | c.1882+60G>A | Intron (SNP) | VAF 28/208 reads (13%) | called by muse, varscan2
- CHP2 | c.67+70G>T | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, varscan2
- COQ9 | c.*508G>A | 3'UTR (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- CYP2B7P | n.699+131A>T | Intron (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- DDHD1 | c.1846+2575G>T | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- DNMT3A | c.448+10C>T | Intron (SNP) | VAF 41/274 reads (15%) | called by muse, mutect2, varscan2
- DPPA4 | c.679+94C>T | Intron (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- DST | c.4297-4101G>T | Intron (SNP) | VAF 22/491 reads (4%) | called by muse, mutect2
- EIF3E | c.471+1387C>A | Intron (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- FAM122B | c.*856T>A | 3'UTR (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- FAM183BP | n.794A>T | RNA (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- FHL1 | c.*272C>A | 3'UTR (SNP) | VAF 33/406 reads (8%) | called by muse, mutect2
- GTF2IRD2P1 | n.837C>G | RNA (SNP) | VAF 57/490 reads (12%) | called by muse, mutect2, varscan2
- HMGN1 | c.127-610G>T | Intron (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+321G>T | Intron (SNP) | VAF 52/243 reads (21%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2372G>T | Intron (SNP) | VAF 108/746 reads (14%) | called by muse, mutect2, varscan2
- IGKV2-30 | c.-9C>A | 5'UTR (SNP) | VAF 31/301 reads (10%) | catalogued as rs1233399063; called by muse, mutect2, varscan2
- KCNIP4 | c.61+251141G>A | Intron (SNP) | VAF 8/147 reads (5%) | called by muse, mutect2
- KCTD10 | c.-26G>T | 5'UTR (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.190C>A | RNA (SNP) | VAF 67/405 reads (17%) | catalogued as COSV55597858; called by muse, mutect2, varscan2
- KLHL29 | c.-45-38096C>T | Intron (SNP) | VAF 18/126 reads (14%) | catalogued as rs1424654782; called by muse, mutect2, varscan2
45 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 45 other) are not listed here.
